CCDI case PBCNSE — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/c951d4b4-9768-46d6-9a5f-bbbacf0732c4

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Pineoblastoma: ICD-O-3 morphology code: 9362/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 11.6 years (4,221 days).

Biospecimens (2 samples)
- Sample 0DWD1N: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DWD2F: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
